TARGET case TARGET-30-PAPVEB — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/865d47cc-815f-5f64-ad3c-68026de20912

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 1,211 days (3.3 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 4.7 years (1,720 days); Year of diagnosis: 2006; Days to last follow up: 1,211 days (3.3 years); Cog neuroblastoma risk group: Low Risk; Inpc grade: Differentiating; INSS stage: Stage 2B; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL0621.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (3 entries)
- Days to follow up: 263 days; Progression or recurrence anatomic site: Bone marrow; Days to first event: 263 days; First event: Relapse.
- Days to follow up: 263 days; Progression or recurrence anatomic site: Bone, NOS.
- Days to follow up: 1,211 days (3.3 years); Year of follow up: 2010.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (3 samples)
- Sample TARGET-30-PAPVEB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPVEB-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-30-PAPVEB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1211
- Protocol: ANBL00B1, ANBL0621
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.12
- Histology: Unfavorable
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor v/s Stroma: 60/40
- Site of Relapse: Bone; Bone Marrow
- Relapse Percent Tumor: 90
